TCGA case TCGA-EB-A5VV — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/080bb1f8-f20c-4daa-9de3-b5782b69583c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 74 years; Vital status: Alive.

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.4; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: Progression; Age at diagnosis: 75.5 years (27,562 days); Days to diagnosis: 198 days; Prior treatment: No; Days to last follow up: 214 days.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 74.9 years (27,364 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Sites of involvement: Skin, Head and Neck; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >2.0-4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 214 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 193.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 96 kg; Height: 160 cm; BMI: 37.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EB-A5VV-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 510 mg. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide TCGA-EB-A5VV-06A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EB-A5VV-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EB-A5VV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Breslow thickness at diagnosis: 4; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Head and Neck; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 214 days; disease-specific survival: no event (censored), 214 days; progression-free interval: no event (censored), 214 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EB-A5VV-06A-11D-A32M-01): tumor purity 0.36, ploidy 2, whole-genome doublings 0.
